Somatic mutation profile of tumor specimen TCGA-AP-A0L9-01A (aliquot TCGA-AP-A0L9-01A-11W-A062-09) from TCGA case TCGA-AP-A0L9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.7 years (26,185 days).
Specimen TCGA-AP-A0L9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15253237-7fdb-49c5-997a-2e46fef7c010.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0L9-10A (Blood Derived Normal), aliquot TCGA-AP-A0L9-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4b306dd-7f7c-4cd9-a36a-11da9ae282dd

The open-access MAF lists 75 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 15, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 167/171 reads (98%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 24/26 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.1891C>A p.L631I (on ENST00000373394 / NM_001271696.3; = p.L632I on NM_004299.6) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV53722422; called by muse, mutect2, varscan2
- ABCG2 | c.1944G>T p.L648F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV52948131; called by muse, mutect2, varscan2
- ADCY8 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV53894881, COSV53907491, COSV53918807; called by muse, mutect2, varscan2
- ADGRG4 | c.8890A>G p.R2964G | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54963410; called by muse, mutect2, varscan2
- AHNAK | c.13477G>T p.V4493L | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.237); catalogued as rs771080738, COSV57224692, COSV57225319; called by muse, mutect2
- AL645922.1 | c.1833C>G p.F611L | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as rs750266296, COSV54961927; called by muse, mutect2, varscan2
- ANAPC5 | c.1926T>A p.S642R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV55844387; called by muse, mutect2, varscan2
- ANXA7 | c.922G>C p.E308Q (on ENST00000372919 / NM_001320880.2; = p.E286Q on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760138152, COSV65824144; called by muse, mutect2, varscan2
- APEX2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs918902403, COSV66624350; called by muse, mutect2, varscan2
- ATP12A | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1236838340, COSV54520405; called by muse, mutect2, varscan2
- BEST1 | c.840G>C p.Q280H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57122043; called by muse, mutect2, varscan2
- DHX36 | c.2528T>C p.V843A | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57675737; called by muse, mutect2
- EDC4 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as COSV59303129; called by muse, mutect2, varscan2
- FAT2 | c.5120C>T p.S1707L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV55816663; called by muse, mutect2, varscan2
- FZD6 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV62472220; called by muse, mutect2, varscan2
- H3C2 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV52519518; called by muse, mutect2, varscan2
- ITGA10 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65198552; called by muse, mutect2, varscan2
- KLHL42 | c.1341T>A p.H447Q | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); catalogued as COSV67146105; called by muse, mutect2, varscan2
- MARCHF6 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV56884985; called by muse, mutect2, varscan2
- MORC4 | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55245368, COSV99717510; called by muse, mutect2, varscan2
- MTA3 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68136052; called by muse, mutect2, varscan2
- MYOM3 | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV58398276; called by muse, mutect2
- NID1 | c.1255A>G p.T419A | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV51625850; called by muse, mutect2, varscan2
- NRAS | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54755298; called by muse, mutect2, varscan2
- OR10A2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs750033071, COSV100225020, COSV56300107; called by muse, mutect2
- OR51M1 | c.800T>C p.M267T | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV60785180; called by muse, mutect2, varscan2
- OR5AS1 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV57982732; called by muse, mutect2
- OR6K3 | c.700G>A p.V234I (on ENST00000368146; = p.V218I on NM_001005327.2) | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63746210; called by muse, mutect2, varscan2
- PAFAH1B1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as CD982845, COSV68210491; called by muse, mutect2, varscan2
- PDS5B | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.327); catalogued as COSV59724293, COSV59731725; called by muse, mutect2, varscan2
- PIWIL3 | c.1416G>C p.L472F | Missense Mutation (SNP) | VAF 93/170 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV59997309; called by muse, mutect2, varscan2
- PKHD1L1 | c.5698A>G p.T1900A | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV65749442; called by muse, mutect2, varscan2
- PLVAP | c.1170C>G p.I390M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53086820; called by muse, mutect2
- POLB | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55347998; called by muse, mutect2, varscan2
- RAD9B | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63778446; called by muse, mutect2, varscan2
- RASSF3 | c.662C>A p.T221K | Missense Mutation (SNP) | VAF 95/130 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV51686753; called by muse, mutect2, varscan2
- ROBO2 | c.3197G>T p.G1066V | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV59917202, COSV59930020; called by muse, varscan2
- RTTN | c.4564+2T>C p.X1522_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | catalogued as rs967089787, COSV55349589; called by muse, mutect2, varscan2
- SCYL1 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV54214534; called by muse, mutect2, varscan2
- SHB | c.1415G>T p.S472I | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66630030; called by muse, mutect2
- STIM2 | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV52842065; called by muse, mutect2, varscan2
- STS | c.1619C>G p.P540R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV54270777; called by muse, mutect2, varscan2
- SYN2 | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 334/437 reads (76%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV70286025; called by muse, mutect2, varscan2
- SYNJ1 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59153969; called by muse, mutect2, varscan2
- TAS2R39 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71470973; called by muse, mutect2, varscan2
- TFAP2B | c.899del p.R300Pfs*20 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | catalogued as COSV53829366, COSV53830086; called by mutect2, pindel, varscan2
- THADA | c.3308C>T p.S1103F | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57690005; called by muse, mutect2, varscan2
- TRIM49 | c.1250C>G p.A417G | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV100316159, COSV61671548; called by muse, mutect2, varscan2
- XRN1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs1164318998, COSV53816116; called by muse, mutect2, varscan2
- ZBTB33 | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV58534732; called by muse, mutect2, varscan2
- ZNF292 | c.7358C>T p.T2453M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1432422417, COSV60544343; called by muse, mutect2, varscan2
- ZNF532 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 220/233 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1377659916, COSV60174794; called by muse, mutect2, varscan2
- ZNF804B | c.2952G>C p.Q984H | Missense Mutation (SNP) | VAF 166/308 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.707); catalogued as COSV60844720; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58349827, COSV58349844; called by muse, mutect2, varscan2
- ZNF99 | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV68056246; called by muse, mutect2, varscan2
- COL17A1 | c.2441C>T p.S814L | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- TULP4 | c.2034_2072del p.P679_I691del | In Frame Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel
- CEP350 | c.4572T>G p.A1524= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV62607669; called by muse, mutect2, varscan2
- EXPH5 | c.1596A>G p.S532= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs1291019543, COSV56206471; called by muse, mutect2, varscan2
- FLACC1 | c.588G>A p.L196= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV53781955, COSV53786380; called by muse, mutect2, varscan2
- GCC1 | c.2199A>G p.L733= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as COSV58463424; called by muse, mutect2
- KCNS3 | c.957C>T p.H319= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs1161324269, COSV100411312, COSV58408367; called by muse, mutect2, varscan2
- KIF13B | c.2760C>T p.C920= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV72954591; called by muse, mutect2
- OR2G2 | c.498C>T p.T166= | Silent (SNP) | VAF 52/308 reads (17%) | catalogued as COSV60741569; called by muse, mutect2, varscan2
- PCDHGA6 | c.243C>T p.N81= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as rs1343594345, COSV54002642; called by muse, mutect2, varscan2
- PKHD1 | c.6000C>T p.S2000= | Silent (SNP) | VAF 124/424 reads (29%) | catalogued as rs780347387, COSV61875987; called by muse, mutect2, varscan2
- PSD4 | c.2665T>C p.L889= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1158246342, COSV55528888; called by muse, mutect2, varscan2
- RANBP6 | c.3072C>G p.L1024= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV52390843; called by muse, mutect2, varscan2
- SLITRK3 | c.2880T>G p.L960= | Silent (SNP) | VAF 32/370 reads (9%) | catalogued as COSV53851784, COSV99579620; called by muse, mutect2
- SP140 | c.2478C>T p.I826= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV100613757, COSV59453382; called by muse, mutect2, varscan2
- TIGD3 | c.1302C>T p.A434= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV52890764; called by muse, mutect2, varscan2
- TKTL1 | c.1716C>T p.S572= | Silent (SNP) | VAF 66/86 reads (77%) | catalogued as rs782421112, COSV54214223; called by muse, mutect2, varscan2
- SNORD116-20 | n.30C>T | RNA (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
